Gene-level copy-number profile of tumor specimen TCGA-EI-6883-01A from TCGA case TCGA-EI-6883, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 63.7 years (23,268 days).
Specimen TCGA-EI-6883-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.f5b0d29c-9b7e-446a-a7b5-2eb3346d7162.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EI-6883-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/120d01c5-790a-46b3-9e28-998171c5795f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 12,902; copy number 2: 32,624; copy number 3: 11,726; copy number 4: 1,665; copy number 5: 899.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-EI-6883-01): tumor purity 0.8, ploidy 2.18, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,884,250–14,935,363, 2 genes: MACROD2-AS1, AL138808.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 899 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:30,214,765–64,313,132, 899 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,516. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
